Somatic mutation profile of tumor specimen 0DYV13 from CCDI case PBCTDI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 0.7 years (254 days).
Specimen 0DYV13: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4564b056-5037-4bd5-b5df-65335f6d8db7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYV1H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07633eb9-9c00-4517-bbdb-70eec1eced8f

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR4C15 | c.481G>T p.A161S (on ENST00000314644; = p.A107S on NM_001001920.2) | Missense Mutation (SNP) | VAF 60/1282 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.911); catalogued as COSV58951148; called by muse, mutect2
- DIAPH3 | c.2165A>C p.N722T (on ENST00000400324 / NM_001042517.2; = p.N459T on NM_030932.3) | Missense Mutation (SNP) | VAF 197/579 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LAMC3 | c.4212G>T p.L1404F | Missense Mutation (SNP) | VAF 229/746 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- SLC12A6 | c.683G>T p.C228F (on ENST00000354181 / NM_001365088.1; = p.C177F on NM_005135.2) | Missense Mutation (SNP) | VAF 86/1014 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- SH3PXD2B | c.96G>A p.T32= | Silent (SNP) | VAF 322/841 reads (38%) | catalogued as rs1032135775; called by muse, mutect2, varscan2
